Gene-level copy-number profile of tumor specimen TCGA-QQ-A5VA-01A from TCGA case TCGA-QQ-A5VA, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.9 years (22,231 days).
Specimen TCGA-QQ-A5VA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.980b26cd-21a6-4517-826c-71f21874bfb1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QQ-A5VA-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8987ca73-e92d-4ccc-bb2c-6af999e4ff76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 136; copy number 1: 4,855; copy number 2: 33,037; copy number 3: 15,055; copy number 4: 2,508; copy number 5: 842; copy number 6: 1,008; copy number 7: 1,013; copy number 8: 277; copy number 9: 601; copy number 11: 143; copy number 12: 127; copy number 13: 88; copy number 14: 8; copy number 15: 23; copy number 16: 51; copy number 17: 7; copy number 19: 9; copy number 24: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QQ-A5VA-01A-12D-A32H-01): tumor purity 0.33, ploidy 2.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 136 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–746,106, 19 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1.
- chr9:4,299,390–4,666,674, 6 genes: AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6.
- chr9:21,304,326–28,888,955, 93 genes (broad region; genes not listed).
- chr12:115,569,394–115,718,013, 4 genes: AC009803.2, AC009803.1, UBA52P7, RN7SL865P.
- chr12:132,986,365–133,214,832, 14 genes: ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,865 genes in 57 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–25,174,305, 345 genes, copy number 5–8 (broad region; genes not listed).
- chr3:57,755,450–58,178,374, 5 genes, copy number 7 (within-gene range 2–7): SLMAP, PPIAP16, FLNB, FLNB-AS1, AC137936.1.
- chr3:135,925,891–138,485,755, 43 genes, copy number 7: AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1, HSPA8P9, CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1.
- chr3:194,685,883–195,550,581, 21 genes, copy number 7: FAM43A, AC106706.1, AC106706.2, LINC01968, AC090505.1, LINC01972, AC090505.2, XXYLT1, XXYLT1-AS1, MIR3137, RN7SL36P, XXYLT1-AS2, RNU6-25P, AC090018.2, ACAP2, ACAP2-IT1, AC090018.1, Y_RNA, PPP1R2, RNU6ATAC24P, AC069213.1.
- chr3:196,988,621–198,222,513, 37 genes, copy number 6 (within-gene range 2–6): MELTF, DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:49,096–5,893,086, 162 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:51,843,000–54,298,245, 46 genes, copy number 6: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA.
- chr4:89,836,408–91,601,913, 7 genes, copy number 8 (within-gene range 2–8): SNCA-AS1, MMRN1, AC105445.1, CCSER1, RN7SKP248, AC093729.1, TMSB4XP8.
- chr5:58,198–34,651,888, 526 genes, copy number 5–12 (broad region; genes not listed).
- chr5:35,429,064–38,198,148, 52 genes, copy number 6–8: U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1.
- chr7:11,180,902–20,590,085, 101 genes, copy number 6–17 (broad region; genes not listed).
- chr7:21,215,537–21,945,903, 8 genes, copy number 14: RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L.
- chr7:23,310,209–23,897,335, 19 genes, copy number 11 (within-gene range 3–11): IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1.
- chr7:25,134,692–25,500,443, 10 genes, copy number 12 (within-gene range 3–12): C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2.
- chr7:26,667,068–30,179,014, 99 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr7:36,146,842–36,724,549, 12 genes, copy number 11 (within-gene range 1–11): AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN, AC006960.2, AOAH, AOAH-IT1.
- chr7:37,585,500–38,378,804, 32 genes, copy number 9: NECAP1P1, GPR141, EPDR1, GPR141BP, AC018634.1, NME8, SFRP4, STARD3NL, TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr8:150,584–2,838,823, 55 genes, copy number 11–19 (within-gene range 4–19): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1.
- chr8:3,700,492–7,355,359, 70 genes, copy number 6–16 (within-gene range 2–16) (broad region; genes not listed).
- chr8:10,275,499–12,359,391, 88 genes, copy number 5–13 (within-gene range 2–13) (broad region; genes not listed).
- chr8:38,082,122–38,853,028, 31 genes, copy number 11 (within-gene range 2–11): AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2.
- chr8:46,028,804–47,736,306, 36 genes, copy number 7–11 (within-gene range 2–11): AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P.
- chr9:101,028,727–101,793,756, 19 genes, copy number 5: PLPPR1, AL161631.1, AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20, GRIN3A, PPP3R2, MTND3P4.
- chr9:133,761,894–138,203,325, 188 genes, copy number 5 (broad region; genes not listed).
- chr11:77,128,246–78,582,156, 42 genes, copy number 5: MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:79,604,967–89,065,945, 131 genes, copy number 5–24 (within-gene range 3–24) (broad region; genes not listed).
- chr11:101,451,564–102,705,769, 27 genes, copy number 6–15 (within-gene range 2–15): TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27.
- chr11:108,222,832–109,263,564, 14 genes, copy number 7: ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39.
- chr11:117,314,557–118,316,175, 24 genes, copy number 6: CEP164, AP000892.1, PRR13P3, DSCAML1, AP000711.1, AP001554.1, FXYD2, AP000757.2, FXYD6-FXYD2, AP000757.1, FXYD6, TMPRSS13, IL10RA, SMIM35, RN7SL828P, TMPRSS4, SCN4B, SCN2B, JAML, HSPE1P18, MPZL3, MPZL2, AP002800.1, CD3E.
- chr11:120,211,032–120,333,686, 4 genes, copy number 6: OAF, POU2F3, AP001150.1, TLCD5.
- chr14:18,333,726–20,609,884, 131 genes, copy number 6 (broad region; genes not listed).
- chr14:20,955,487–21,104,722, 16 genes, copy number 7 (within-gene range 3–7): RNASE2, RN7SL189P, AL355922.2, METTL17, AL161668.3, SLC39A2, NDRG2, MIR6717, TPPP2, AL161668.4, AL161668.2, RNASE13, RNASE7, RNASE8, ARHGEF40, ZNF219.
- chr14:22,829,879–25,432,234, 132 genes, copy number 7 (broad region; genes not listed).
- chr14:27,258,717–28,418,612, 5 genes, copy number 7: AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1.
- chr14:29,210,986–29,500,460, 4 genes, copy number 6 (within-gene range 2–6): AL133166.1, AL158058.1, AL158058.2, RNU11-5P.
- chr15:56,394,321–59,523,555, 81 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr15:66,504,959–66,956,518, 9 genes, copy number 7 (within-gene range 4–7): ZWILCH, LCTL, LINC01169, SMAD6, AC013564.1, AC110048.1, AC110048.2, AC093334.1, LINC02206.
- chr15:68,054,309–101,933,350, 885 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:10,383,132–18,328,056, 235 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr18:21,529,284–25,056,760, 85 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,558. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
